Surgical pathology report (de-identified scan), TCGA case TCGA-58-A46N, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-58-A46N-01A (Primary Tumor).

Pathology Report-Summary:

Material:

lung, right, lower lobe: 19.0 x 13.0 x 8.0 cm

tumor: 3.5 x 2.0 x 2.2 cm

Diagnosis:

Squamous Cell Carcinoma, basaloid

pT2a, pN0 (0/38), pMx, G3

Pathologist:

ICD-O-3

Carcinoma, Squamous cell,
basaloid 8083/3

Site: lung, lower lobe

9-512
RD

C34.3

9/21/12

Source: NCI Genomic Data Commons file 59fa87b4-d0b0-4b1e-92b8-eb9bb698524f (TCGA-58-A46N.95A2F9CB-DFB3-441E-9F24-467D9AB343F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).